Surgical pathology report (de-identified scan), TCGA case TCGA-09-0364, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-0364-01A (Primary Tumor).

[page 1 of 4]
A: Tumor mass, portion of right tube and ovary (EC)

B: Cervix, uterus left ovary and tube

C: Tumor adherent to rectum

D: Ovary Blocks

1 of 4

[page 2 of 4]
[REDACTED]

Lymphatic/vascular invasion: Absent.

Sites of metastasis in pelvis: Tumor is present in the tissue removed from the pelvis in part B as well as

in the tissue adherent to the rectum in part C.

Pelvic lymph nodes: None sampled.

Sites of metastasis in abdomen: Not sampled.

Para-aortic lymph nodes: None sampled.

Peritoneal cytology: Positive [REDACTED]

Other abnormalities: Microscopic endometriosis is present in the tissue adherent to the rectum.

FIGO stage: At least IIC (no lymph nodes or peritoneum submitted).

TNM stage: At least pT2cNXMX (no lymph nodes or peritoneum submitted).

Additional comments: The tumor is quite mitotically active, showing up to 7 mitoses/high power field, some of which are atypical. Large areas of necrosis are present. Tumor is present in the tissue submitted

as right ovary, in the tissue designated as being from the pelvis in part B, and in the tissue adherent to the

rectum (part C). The left ovary and fallopian tube are free of tumor. [REDACTED] [REDACTED] [REDACTED]

[REDACTED], was informed

of these findings on [REDACTED]

Intraoperative Consult Diagnosis

1. (Specimen A) Right ovary and Fallopian tube, right salpingo-oophorectomy: Carcinoma consistent with ovarian primary. [REDACTED]

Clinical History

The patient is an [REDACTED] with a preoperative diagnosis of ovarian cancer. Patient undergoes a transabdominal hysterectomy and bilateral salpingo-oophorectomy.

Gross Description

The specimen is received in four parts (A-D), each labeled with the patient's name and number. Part D is for research purposes.

Part A is received fresh, labeled "tumor mass--portion of right tube and ovary", and consists of multiple tan

and maroon, soft, segments of tissue measuring 15.3 x 12.2 x 10.3 cm. Due to the large amount of apparent tumor, normal architectural structures are not identified. No fallopian tube, residual ovary or identifiable ovarian capsule is apparent. Representative section is submitted for frozen section analysis #1

with subsequent placement into cassette A1. Additional representative sections taken at 1.0 cm increments

are submitted in cassettes A2-A7.

Part B is received in formalin, labeled "cervix--uterus--portion of tumor--left ovary and tubes", and

[page 3 of 4]
[REDACTED]

consists

of a uterus and cervix with attached left tube and ovary as well as an additional segment of fallopian tube

with attached perimetrium (separate from the main specimen) and multiple separate segments of tissue with an apparent papillated tumor weighing 199.8 gm. A call was made to [REDACTED] who stated that this separate tumor tissue is from the pelvis. The uterus measures 7.8 cm from fundus to cervix, 5.1 cm from cornu to cornu, 4.3 cm from anterior to posterior, and is oriented by the relation of the

round ligaments to the Fallopian tubes as well as the peritoneal reflections. The serosa is distorted by approximately six subserosal nodules ranging in size from 0.1 x 0.1 x 0.1 cm to 1.1 x 0.8 x 0.5 cm. The uterine cavity sounds to 4.8 cm. The cervix measures 2.6 cm in length x 2.1 cm in width. The external os

is fishmouth and measures 0.6 cm in width. The surgical incision margins of the uterus are inked in black.

The uterus is opened along the lateral borders. The endometrium is tan, measures <0.1 mm, and contains

no polyps. The myometrium measures 1.1 cm and contains multiple subserosal and intramural leiomyomas ranging in size from 0.1 cm in all dimensions to 1.6 x 1.5 x 1.1 cm in dimension. On cut section, they are well-circumscribed, firm, white-tan and have a whorled appearance. The left Fallopian tube measures 5.8 cm in length x 0.5 cm in average diameter. The fimbria are lush. On cut section, the tube is unremarkable. The left ovary measures 2.7 x 1.1 x 0.4 cm. The surface is smooth. On cut section,

the ovary is unremarkable. One of the separate fragments of tissue has a Fallopian tube within it measuring 5.2 cm in length x 0.5 cm in average diameter. On cut section, the tube is unremarkable.

Representative sections are submitted as follows:

Cassette B1: Anterior cervix.

Cassette B2: Posterior cervix.

Cassette B3: Anterior myometrium.

Cassette B4: Posterior myometrium.

Cassette B5: Subserosal and intramural nodules.

Cassette B6: Left ovary and tube.

Cassette B7: Multiple sections of separate soft tissue ("pelvic tumor").

Cassette B8: Separate segment of fallopian tube.

Cassette B9: Additional endometrial sections.

Part C, labeled "tumor--adherent to rectum", consists of multiple maroon and tan, fragmented, soft segments of tissue measuring 5.1 x 5.1 x 3.6 cm in aggregate. On cut section, the segments appear to represent segments of large bowel with serosal hemorrhage with small white islands of tumor adherent to

the large bowel serosa. Representative section of the tissue is submitted in cassettes C1-C3.

Part D is submitted as ovary project blocks are 5 brown plastic cassettes containing small tissue fragments.

Processed for research in cassettes D1-D5.

[REDACTED]

Other Specimens

[page 4 of 4]
[REDACTED]

Specimen(s) Received: Vaginal, Thin Prep

Final Diagnosis

Vaginal, Thin Prep

CELLULAR CHANGES WITHIN NORMAL LIMITS.

SPECIMEN ADEQUACY:

Satisfactory for evaluation.

[REDACTED]

[REDACTED]

Specimen(s) Received: Vaginal, Thin Prep

Final Diagnosis

Vaginal, Thin Prep

CELLULAR CHANGES WITHIN NORMAL LIMITS.

Atrophic pattern

SPECIMEN ADEQUACY:

Satisfactory for evaluation.

[REDACTED]

[REDACTED]

Specimen(s) Received: Ascitic Fluid

Final Diagnosis

Ascitic Fluid

ADENOCARCINOMA, METASTATIC.

[REDACTED]

[REDACTED]

Specimen(s) Received: STOMACH

Final Diagnosis

STOMACH, ANTRUM, BIOPSY: FOCAL CHRONIC ACTIVE GASTRITIS, NO HELICOBACTER PYLORI IDENTIFIED.

Conversion

[REDACTED]

Source: NCI Genomic Data Commons file ed2e34e9-829a-4db1-a835-9bf64420173d (TCGA-09-0364.27B9EFD3-7748-4DEB-96A2-3869A19BFA6F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).